HCMI case HCM-CSHL-0837-D01 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ef761af-e22d-44ac-8718-c09cbe588a0b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (1)
1. Intraductal papillary-mucinous carcinoma, non-invasive: ICD-O-3 morphology code: 8453/2; ICD-10 code: D01.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: Premalignant; Age at diagnosis: 67.7 years (24,735 days); AJCC staging edition: 8th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: M0; Tumor grade: GX; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 15.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 8 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 655 days (1.8 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 417.

Molecular and laboratory tests
- CA19-9: 77.
- CEA: 1.3 ng/mL; Blood test normal range upper: 3.8.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Intraductal Papillary Mucinous Neoplasm; Comorbidity method of diagnosis: Radiology.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Other.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 170.2 cm; BMI: 22.
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Diabetes treatment type: Biguanide.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol intensity: Non-Drinker; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-CSHL-0837-D01-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0837-D01-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
